Somatic mutation profile of tumor specimen TCGA-09-1673-01A (aliquot TCGA-09-1673-01A-01W-0633-09) from TCGA case TCGA-09-1673, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 50.9 years (18,599 days).
Specimen TCGA-09-1673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e77166a-e13d-46b4-8423-882bbb6e2b8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-1673-10A (Blood Derived Normal), aliquot TCGA-09-1673-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dcefe88-bbbc-479c-b815-f5ebba64f9cc

The open-access MAF lists 44 somatic variants for this specimen: 37 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 6, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 150/161 reads (93%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABI1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61019297; called by muse, mutect2, varscan2
- ALDOB | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150407710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF10 | c.574G>C p.E192Q (on ENST00000398564; = p.E167Q on NM_014629.4) | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV50668625; called by muse, mutect2, varscan2
- ATP9B | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56948625, COSV56963344; called by muse, mutect2, varscan2
- CADPS2 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 52/154 reads (34%) | catalogued as rs774509494, COSV57379783; called by mutect2, varscan2
- CBWD1 | c.1152G>T p.W384C | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.312); catalogued as COSV58702198; called by muse, mutect2, varscan2
- CDK12 | c.1028_1046+14del p.X343_splice | Splice Site (DEL) | VAF 52/75 reads (69%) | catalogued as COSV71002302; called by mutect2, pindel, varscan2
- CEP112 | c.2554A>C p.K852Q (on ENST00000392769 / NM_001353127.1; = p.K108Q on NM_001037325.3) | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV58067336; called by muse, mutect2, varscan2
- CYP4F11 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV56125991; called by muse, mutect2
- DRD2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 111/184 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60757563; called by muse, mutect2, varscan2
- ENOX2 | c.1622T>G p.I541S (on ENST00000338144 / NM_001382520.1; = p.I512S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 171/368 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57656506; called by muse, mutect2, varscan2
- FBXO39 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 99/107 reads (93%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV58622748; called by muse, mutect2, varscan2
- FLG | c.9628C>T p.R3210C | Missense Mutation (SNP) | VAF 163/793 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs571141981, COSV64246321; called by muse, mutect2, varscan2
- FMR1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.111); catalogued as rs1557182644, COSV54424209; called by muse, mutect2, varscan2
- FOXO4 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV58576179; called by muse, mutect2, varscan2
- GUCY2F | c.2446A>G p.K816E | Missense Mutation (SNP) | VAF 181/539 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV54306841, COSV99028636; called by muse, mutect2, varscan2
- LAMB1 | c.4009G>T p.A1337S | Missense Mutation (SNP) | VAF 258/497 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV55968887; called by muse, mutect2, varscan2
- LAMC3 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs751314241, COSV63094440; called by muse, mutect2, varscan2
- LIPN | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV68384389; called by muse, mutect2, varscan2
- MCM6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV99918956; called by muse, mutect2
- MYMK | c.649T>G p.C217G | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60601364; called by muse, mutect2, varscan2
- NDST1 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99938777; called by muse, mutect2
- NEIL1 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs376283006; called by muse, mutect2, varscan2
- NHLRC3 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV65463403; called by muse, mutect2, varscan2
- OR13A1 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs548749406, COSV65573131; called by muse, mutect2, varscan2
- OR4Q3 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 136/306 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV59179824, COSV59179919; called by muse, mutect2, varscan2
- PDE7B | c.938T>A p.F313Y | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57505308; called by muse, mutect2, varscan2
- PIEZO2 | c.7987G>C p.G2663R | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53286680, COSV53290417, COSV53292839; called by muse, mutect2, varscan2
- SLC12A3 | c.617T>A p.L206H | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99344131; called by muse, mutect2
- SNRPN | c.368C>G p.A123G | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as COSV57599692; called by muse, mutect2, varscan2
- TAFA1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs550621255, COSV72040343; called by muse, mutect2, varscan2
- TBC1D1 | c.2734A>G p.M912V | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1560256524, COSV54725036; called by muse, mutect2, varscan2
- TTN | c.99922C>T p.R33308C (on ENST00000591111; = p.R25884C on NM_003319.4) | Missense Mutation (SNP) | VAF 42/273 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs576270358, COSV59888459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WASL | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV56135470; called by muse, mutect2, varscan2
- ZMYND15 | c.1650dup p.E551Rfs*33 (on ENST00000433935 / NM_001136046.3; = p.E512Rfs*33 on NM_032265.2) | Frame Shift Ins (INS) | VAF 9/82 reads (11%) | catalogued as rs1484755918; called by mutect2, pindel, varscan2
- GLUD2 | c.537_541delinsC p.G180Vfs*29 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by pindel, varscan2*
- BRD9 | c.933G>T p.R311= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60249216; called by muse, mutect2, varscan2
- KRT2 | c.492C>T p.N164= | Silent (SNP) | VAF 80/153 reads (52%) | catalogued as rs201708557, COSV59012212; called by muse, mutect2, varscan2
- MMP2 | c.1699C>A p.R567= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs760625271, COSV54604188, COSV54606885; called by muse, mutect2, varscan2
- MRO | c.471G>A p.G157= | Silent (SNP) | VAF 174/444 reads (39%) | catalogued as rs1334528452, COSV56497838; called by muse, mutect2, varscan2
- N4BP2L1 | c.525G>T p.R175= | Silent (SNP) | VAF 70/134 reads (52%) | catalogued as COSV58413740; called by muse, mutect2, varscan2
- SCML2 | c.1623A>G p.S541= | Silent (SNP) | VAF 142/311 reads (46%) | catalogued as COSV52624148; called by muse, mutect2, varscan2
- SCML4 | c.157-5779C>G | Intron (SNP) | VAF 65/137 reads (47%) | catalogued as rs751051163, COSV64637312; called by muse, mutect2, varscan2
